Somatic mutation profile of tumor specimen TCGA-85-8288-01A (aliquot TCGA-85-8288-01A-11D-2293-08) from TCGA case TCGA-85-8288, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 70.2 years (25,629 days).
Specimen TCGA-85-8288-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 197e6bb1-b69c-4c9b-8c7f-a22199e99d2c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-85-8288-10A (Blood Derived Normal), aliquot TCGA-85-8288-10A-01D-2293-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4eac9ac9-6177-49b1-a24f-9dc561726388

The open-access MAF lists 273 somatic variants for this specimen: 197 protein-altering or splice-affecting, 71 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 157, Silent 71, Nonsense Mutation 17, Frame Shift Del 9, Splice Site 6, Frame Shift Ins 5, Intron 3, Splice Region 2, In Frame Del 1, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PCNT | c.1975dup p.D659Gfs*18 | Frame Shift Ins (INS) | VAF 33/142 reads (23%) | catalogued as rs1555956600; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ACAN | c.1811C>G p.T604R | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as rs758736365, COSV100717717; called by muse, varscan2
- ACTA1 | c.391G>A p.V131M | Missense Mutation (SNP) | VAF 40/313 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.242); catalogued as rs1273559032, COSV100796723; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAMTS16 | c.1651G>T p.E551* | Nonsense Mutation (SNP) | VAF 38/97 reads (39%) | catalogued as COSV99940801; called by muse, mutect2, varscan2
- ADAMTSL3 | c.1763A>C p.E588A | Missense Mutation (SNP) | VAF 50/184 reads (27%) | SIFT tolerated (0.7); PolyPhen benign (0.007); catalogued as COSV99718042; called by muse, mutect2, varscan2
- ADD3 | c.1102G>T p.E368* | Nonsense Mutation (SNP) | VAF 35/93 reads (38%) | catalogued as COSV53321061, COSV99523315; called by muse, mutect2, varscan2
- AK8 | c.829G>T p.V277L | Missense Mutation (SNP) | VAF 92/234 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV100049900; called by muse, mutect2, varscan2
- AKR1C4 | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as rs1367695039, COSV99578619; called by muse, mutect2, varscan2
- APBB2 | c.1012G>A p.V338I (on ENST00000295974 / NM_001166050.2; = p.V339I on NM_004307.2) | Missense Mutation (SNP) | VAF 33/152 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV99922812; called by muse, mutect2, varscan2
- ASPH | c.1655A>G p.K552R | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as COSV101063718; called by muse, mutect2, varscan2
- ATF7IP | c.2160A>G p.V720= | Splice Region (SNP) | VAF 28/75 reads (37%) | catalogued as rs1442801779, COSV53776046; called by muse, mutect2, varscan2
- ATP13A2 | c.415G>T p.E139* | Nonsense Mutation (SNP) | VAF 87/280 reads (31%) | catalogued as COSV100454049, COSV58699721; called by muse, mutect2, varscan2
- ATP6V1B1 | c.712T>G p.F238V | Missense Mutation (SNP) | VAF 49/159 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99313973; called by muse, mutect2, varscan2
- B3GALT5 | c.857T>A p.F286Y | Missense Mutation (SNP) | VAF 54/168 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100563347; called by muse, mutect2, varscan2
- BPIFB4 | c.1637+1G>T p.X546_splice | Splice Site (SNP) | VAF 15/84 reads (18%) | catalogued as COSV100971486; called by muse, mutect2
- BTN2A1 | c.155A>G p.H52R | Missense Mutation (SNP) | VAF 43/126 reads (34%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.966); catalogued as rs1239558513, COSV100438501; called by muse, mutect2, varscan2
- CACNA1G | c.6722G>C p.R2241P | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV100661629, COSV61736405; called by muse, mutect2, varscan2
- CASP8 | c.306-2A>G p.X102_splice (on ENST00000432109 / NM_033355.3; = p.X134_splice on NM_001228.4) | Splice Site (SNP) | VAF 14/31 reads (45%) | catalogued as COSV99965036; called by muse, mutect2, varscan2
- CCDC191 | c.31T>C p.S11P | Missense Mutation (SNP) | VAF 136/301 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV55559279, COSV99846866; called by muse, mutect2, varscan2
- CD1B | c.121T>C p.W41R | Missense Mutation (SNP) | VAF 103/373 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.229); catalogued as COSV100939213; called by muse, mutect2, varscan2
- CDT1 | c.1325C>T p.P442L | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs200199040, COSV99967153; called by muse, mutect2, varscan2
- CFAP43 | c.1505A>G p.N502S | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs761809673, COSV53379374; called by muse, mutect2, varscan2
- CFHR5 | c.519C>G p.F173L | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as COSV56825860, COSV99888404; called by muse, mutect2, varscan2
- CHAT | c.1300G>T p.G434C | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100339999; called by muse, mutect2, varscan2
- CHP2 | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs373586872; called by muse, mutect2, varscan2
- CHRNA6 | c.818C>T p.T273M | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs144350308; called by muse, mutect2, varscan2
- CLPX | c.784A>T p.N262Y | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.332); catalogued as COSV100269419; called by muse, mutect2, varscan2
- COG8 | c.1256A>T p.Q419L | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.065); catalogued as COSV99650688; called by muse, mutect2, varscan2
- COL8A1 | c.685G>A p.G229R | Missense Mutation (SNP) | VAF 31/181 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53738150; called by muse, mutect2, varscan2
- CSMD3 | c.4295C>A p.P1432H (on ENST00000297405 / NM_001363185.1; = p.P1328H on NM_052900.3) | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52288962, COSV52289308; called by muse, mutect2, varscan2
- CTDSPL2 | c.557A>G p.E186G | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.681); catalogued as COSV99526764, COSV99527258; called by muse, mutect2, varscan2
- CUX2 | c.2654C>A p.P885H | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99919298; called by muse, mutect2, varscan2
- CYRIA | c.462C>A p.D154E | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100838312; called by muse, varscan2
- DAZAP1 | c.238A>T p.I80F | Missense Mutation (SNP) | VAF 75/252 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99245135; called by muse, mutect2, varscan2
- DIP2C | c.4295-2A>G p.X1432_splice | Splice Site (SNP) | VAF 28/109 reads (26%) | catalogued as COSV99791132; called by muse, mutect2, varscan2
- DLC1 | c.4070A>G p.K1357R (on ENST00000276297 / NM_001348081.2; = p.K920R on NM_006094.5) | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.505); catalogued as COSV99362409; called by muse, mutect2, varscan2
- DNAH14 | c.787C>G p.L263V (on ENST00000445597; = p.L136V on NM_144989.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100835865; called by muse, mutect2, varscan2
- DNAH8 | c.7345C>A p.H2449N | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as COSV100544342; called by muse, mutect2, varscan2
- DOCK1 | c.2792T>A p.F931Y | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.023); catalogued as COSV99728624; called by muse, varscan2
- DSC1 | c.2637C>A p.H879Q | Missense Mutation (SNP) | VAF 48/179 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0.046); catalogued as rs754100664, COSV99937492; called by muse, mutect2, varscan2
- DTNA | c.1807G>T p.E603* | Nonsense Mutation (SNP) | VAF 31/116 reads (27%) | catalogued as COSV52003977, COSV99312024; called by muse, mutect2, varscan2
- ECI1 | c.466C>G p.L156V | Missense Mutation (SNP) | VAF 55/178 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as COSV100066690; called by muse, mutect2, varscan2
- EFTUD2 | c.671G>A p.G224E | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV101274530; called by muse, mutect2
- EFTUD2 | c.669T>A p.D223E | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV101274531; called by muse, mutect2
- ERICH3 | c.809T>C p.L270P | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100443951; called by muse, mutect2, varscan2
- F2 | c.1109C>G p.A370G | Missense Mutation (SNP) | VAF 41/140 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); catalogued as COSV100319454; called by muse, mutect2, varscan2
- FBXL18 | c.337G>T p.E113* | Nonsense Mutation (SNP) | VAF 8/37 reads (22%) | catalogued as rs1280050811, COSV101212044; called by muse, mutect2
- FBXO25 | c.66G>C p.W22C | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99366837; called by muse, mutect2, varscan2
- FCMR | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV65567213; called by muse, mutect2, varscan2
- FCRL5 | c.716G>C p.W239S | Missense Mutation (SNP) | VAF 81/271 reads (30%) | SIFT tolerated (0.75); PolyPhen benign (0.243); catalogued as COSV100708780; called by muse, mutect2, varscan2
- FGFR4 | c.1348G>A p.V450M | Missense Mutation (SNP) | VAF 74/183 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.024); catalogued as rs138256705; called by muse, mutect2, varscan2
- FOXG1 | c.1090G>T p.V364L | Missense Mutation (SNP) | VAF 86/224 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV100486678; called by muse, mutect2, varscan2
- FRY | c.4465C>T p.Q1489* | Nonsense Mutation (SNP) | VAF 20/51 reads (39%) | catalogued as COSV100969051; called by muse, mutect2, varscan2
- FSTL5 | c.2203A>G p.T735A | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as COSV100054154; called by muse, mutect2, varscan2
- FUT9 | c.344G>T p.W115L | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.06); catalogued as COSV56159459; called by muse, mutect2, varscan2
- G0S2 | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV65433291; called by muse, mutect2, varscan2
- GP6 | c.724+1del p.X242_splice | Splice Site (DEL) | VAF 24/116 reads (21%) | catalogued as COSV100117403; called by mutect2, pindel, varscan2
- GPR162 | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 41/220 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as rs200629121, COSV99163743; called by muse, mutect2, varscan2
- GPRASP1 | c.562C>A p.P188T | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.052); catalogued as COSV100850968; called by muse, mutect2, varscan2
- GPSM2 | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374722932, COSV99915636; called by muse, mutect2, varscan2
- GYS2 | c.802C>A p.H268N | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as COSV99679656; called by muse, mutect2, varscan2
- HECTD2 | c.427A>T p.K143* | Nonsense Mutation (SNP) | VAF 12/60 reads (20%) | catalogued as COSV99978407; called by muse, mutect2, varscan2
- HECTD4 | c.12403G>A p.V4135I | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated (0.65); PolyPhen benign (0.015); catalogued as rs755402179, COSV101107214; called by muse, mutect2, varscan2
- HELT | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.05); catalogued as COSV100132872; called by muse, mutect2
- HOXB2 | c.272del p.P91Rfs*8 | Frame Shift Del (DEL) | VAF 17/56 reads (30%) | catalogued as rs761024113; called by mutect2, pindel, varscan2
- HRC | c.1354C>A p.H452N | Missense Mutation (SNP) | VAF 43/148 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV99417793; called by muse, mutect2, varscan2
- HRH2 | c.712G>T p.A238S | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.564); catalogued as COSV51575960, COSV99199591; called by muse, mutect2, varscan2
- HTATSF1 | c.28G>T p.D10Y | Missense Mutation (SNP) | VAF 87/166 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV54480906, COSV99511578; called by muse, mutect2, varscan2
- HYLS1 | c.55C>T p.R19* | Nonsense Mutation (SNP) | VAF 19/66 reads (29%) | catalogued as rs143088549; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IGKV1-6 | c.170G>T p.W57L | Missense Mutation (SNP) | VAF 51/132 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs750935261; called by muse, mutect2, varscan2
- IGLV2-18 | c.338C>G p.T113R | Missense Mutation (SNP) | VAF 43/154 reads (28%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as rs1277311126; called by muse, mutect2, varscan2
- IGSF10 | c.118G>T p.E40* | Nonsense Mutation (SNP) | VAF 56/135 reads (41%) | catalogued as COSV99177945; called by muse, mutect2, varscan2
- IGSF11 | c.1166A>G p.N389S (on ENST00000393775 / NM_001015887.3; = p.N388S on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/117 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1223567534, COSV100677209; called by muse, mutect2, varscan2
- IL7R | c.170G>A p.C57Y | Missense Mutation (SNP) | VAF 93/199 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100286165; called by muse, mutect2, varscan2
- ITIH5 | c.1279G>A p.A427T | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.03); catalogued as rs1467593204, COSV53664001, COSV53668973; called by muse, mutect2, varscan2
- JAG1 | c.2798T>G p.V933G | Missense Mutation (SNP) | VAF 45/152 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV99652702; called by muse, mutect2, varscan2
- JUP | c.1715G>A p.R572Q | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs397517298, COSV100159478; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNJ3 | c.82G>T p.G28W | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.189); catalogued as COSV99715565; called by muse, mutect2, varscan2
- KCNK2 | c.1174G>T p.E392* (on ENST00000444842 / NM_001017425.3; = p.E377* on NM_014217.4) | Nonsense Mutation (SNP) | VAF 27/109 reads (25%) | catalogued as COSV101222034, COSV67202918; called by muse, mutect2, varscan2
- KCNN2 | c.1514A>T p.K505M (on ENST00000264773; = p.K717M on NM_021614.4) | Missense Mutation (SNP) | VAF 38/70 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.682); catalogued as COSV99299410; called by muse, mutect2, varscan2
- KCNU1 | c.2677A>T p.T893S | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.839); catalogued as COSV101299115; called by muse, mutect2, varscan2
- KCTD21 | c.404G>A p.S135N | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.258); catalogued as COSV100399688; called by muse, mutect2, varscan2
- KIF13A | c.259C>A p.L87I | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs763146358, COSV99435235; called by muse, mutect2, varscan2
- KIF2B | c.1572G>A p.M524I | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.065); catalogued as COSV99275114; called by muse, mutect2, varscan2
- KMT2C | c.7115A>T p.N2372I | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.274); catalogued as COSV100070370; called by muse, mutect2, varscan2
- KRT71 | c.1297C>A p.R433S | Missense Mutation (SNP) | VAF 30/161 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.209); catalogued as COSV99922091; called by muse, mutect2, varscan2
- L1CAM | c.2785C>A p.Q929K | Missense Mutation (SNP) | VAF 17/22 reads (77%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as CM138922, COSV100649023; called by muse, mutect2, varscan2
- LGR5 | c.385G>A p.V129I | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.206); catalogued as rs750993587, COSV57009397; called by muse, mutect2, varscan2
- LINGO3 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.022); catalogued as rs1022186992, COSV101347238; called by muse, mutect2, varscan2
- LRIT2 | c.685del p.L229* | Frame Shift Del (DEL) | VAF 29/98 reads (30%) | catalogued as COSV60566880; called by mutect2, pindel, varscan2
- LRP1B | c.1884G>C p.R628S | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV101255206, COSV67264930; called by muse, mutect2, varscan2
- LVRN | c.1439G>C p.R480T | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV63497479; called by muse, mutect2, varscan2
- MAGEL2 | c.3280G>T p.G1094C | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.757); catalogued as COSV100045861; called by muse, mutect2, varscan2
- MAGI1 | c.3763C>T p.P1255S | Missense Mutation (SNP) | VAF 65/166 reads (39%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV100440304; called by muse, mutect2, varscan2
- MC2R | c.196T>A p.L66M | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59619363; called by muse, mutect2, varscan2
- MC3R | c.175G>A p.V59I | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV99710535; called by muse, mutect2, varscan2
- MDGA2 | c.926C>A p.A309E (on ENST00000399232 / NM_001113498.2; = p.A11E on NM_182830.4) | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV100636805; called by muse, varscan2
- MEF2C | c.643G>T p.G215W | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60925968, COSV60927089; called by muse, mutect2, varscan2
- MISP | c.254A>G p.E85G | Missense Mutation (SNP) | VAF 38/188 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.246); catalogued as COSV99296734; called by muse, mutect2, varscan2
- MPP6 | c.1036G>T p.A346S | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.934); catalogued as COSV99757393; called by muse, mutect2, varscan2
- MUC17 | c.1991C>A p.T664N | Missense Mutation (SNP) | VAF 136/459 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as COSV100072681; called by muse, mutect2, varscan2
- MUC4 | c.13259A>G p.Y4420C (on ENST00000463781 / NM_018406.7; = p.Y184C on NM_004532.6) | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.97); catalogued as COSV100204278; called by muse, mutect2, varscan2
- NEUROD6 | c.99G>C p.K33N | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV51772503, COSV99773983; called by muse, mutect2, varscan2
- NEUROG2 | c.594C>A p.S198R | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.023); catalogued as rs1305165647, COSV100511794; called by muse, mutect2, varscan2
- NKTR | c.475G>T p.D159Y | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV51774072, COSV99235553; called by muse, mutect2, varscan2
- NLRP5 | c.1932C>A p.D644E | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.084); catalogued as COSV101173547, COSV66762842; called by muse, mutect2, varscan2
- NPC1L1 | c.3769G>A p.A1257T | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148506506, COSV99202613; called by muse, mutect2, varscan2
- NR1H4 | c.954G>T p.K318N (on ENST00000551379 / NM_001206993.2; = p.K304N on NM_005123.4) | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0.017); catalogued as COSV99500372; called by muse, mutect2, varscan2
- NRL | c.221G>T p.W74L | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV99393297; called by muse, mutect2, varscan2
- OPRD1 | c.122G>C p.R41P | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.688); catalogued as COSV99330188; called by muse, mutect2, varscan2
- OR2G3 | c.445T>A p.W149R | Missense Mutation (SNP) | VAF 41/147 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100180562; called by muse, mutect2, varscan2
- OR52E4 | c.400T>C p.Y134H | Missense Mutation (SNP) | VAF 39/78 reads (50%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.452); catalogued as rs1399103467, COSV100389211; called by muse, mutect2, varscan2
- OR56A4 | c.982C>A p.P328T | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.652); catalogued as COSV100417529; called by muse, mutect2, varscan2
- OR5L2 | c.272C>G p.A91G | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV101004286; called by muse, mutect2, varscan2
- OR5R1 | c.196C>A p.L66M | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56571541; called by muse, mutect2, varscan2
- OR8B12 | c.68G>A p.R23Q | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as rs140680123; called by muse, mutect2, varscan2
- OR8G2P | c.772A>G p.M258V | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.017); catalogued as rs1243945114; called by muse, mutect2, varscan2
- OSBP2 | c.1626G>A p.V542= | Splice Region (SNP) | VAF 21/60 reads (35%) | catalogued as COSV100212927; called by muse, mutect2, varscan2
- PCDHB14 | c.1183C>A p.P395T | Missense Mutation (SNP) | VAF 5/97 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.678); catalogued as COSV99505751; called by muse, mutect2
- PCOLCE | c.1091A>G p.Y364C | Missense Mutation (SNP) | VAF 67/208 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99774919; called by muse, mutect2, varscan2
- PEG3 | c.230C>A p.P77Q | Missense Mutation (SNP) | VAF 41/170 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV55639993, COSV99688363; called by muse, mutect2, varscan2
- PHLDB2 | c.905T>G p.L302R | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.852); catalogued as COSV101208479; called by muse, mutect2
- PKNOX2 | c.874C>T p.R292* | Nonsense Mutation (SNP) | VAF 34/108 reads (31%) | catalogued as COSV53543958; called by muse, mutect2, varscan2
- PLCB1 | c.2386A>G p.K796E | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV100570289; called by muse, mutect2
- POM121L12 | c.619A>T p.R207W | Missense Mutation (SNP) | VAF 46/171 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV68694812; called by muse, mutect2, varscan2
- PON1 | c.610T>C p.Y204H | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.56); catalogued as COSV99732172; called by muse, mutect2, varscan2
- POU3F4 | c.624G>T p.L208F | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100937200; called by muse, mutect2, varscan2
- PREP | c.1375A>G p.N459D (on ENST00000369110; = p.N525D on NM_002726.5) | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100963840; called by muse, mutect2, varscan2
- PRF1 | c.1655G>A p.G552E | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.739); catalogued as COSV64614986; called by muse, mutect2, varscan2
- PRKDC | c.3148_3150del p.E1050del | In Frame Del (DEL) | VAF 4/22 reads (18%) | catalogued as rs778725742; ClinVar: uncertain significance; called by mutect2, pindel
- PTCHD3 | c.944T>G p.L315* | Nonsense Mutation (SNP) | VAF 12/174 reads (7%) | catalogued as COSV101438890; called by muse, mutect2
- PTPN13 | c.3959A>T p.D1320V (on ENST00000411767 / NM_080683.3; = p.D1301V on NM_006264.3) | Missense Mutation (SNP) | VAF 39/143 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100364538; called by muse, mutect2, varscan2
- PUM2 | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as rs778508842, COSV57578717; called by muse, mutect2, varscan2
- QARS1 | c.1738A>T p.T580S | Missense Mutation (SNP) | VAF 61/155 reads (39%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.761); catalogued as COSV100069933; called by muse, mutect2, varscan2
- RAC1 | c.203G>A p.R68H | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.325); catalogued as COSV61823416; called by muse, mutect2, varscan2
- REG3A | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.476); catalogued as COSV100532640; called by muse, mutect2, varscan2
- RICTOR | c.2987G>T p.S996I | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as COSV99704720; called by muse, mutect2, varscan2
- RNASEH2A | c.751G>A p.D251N | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV55551813; called by muse, mutect2, varscan2
- RNF111 | c.1159G>A p.V387I | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as rs188638210, COSV100788924; called by muse, mutect2, varscan2
- ROBO3 | c.2252G>A p.G751E | Missense Mutation (SNP) | VAF 37/169 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV101185001; called by muse, mutect2, varscan2
- ROBO4 | c.160C>A p.Q54K | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV100127465; called by muse, mutect2, varscan2
- RP1L1 | c.4816C>T p.R1606C | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as rs759239863, COSV66758372; called by muse, mutect2, varscan2
- RXFP3 | c.1373G>A p.G458E | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.12); catalogued as COSV100347467; called by muse, mutect2, varscan2
- RYR1 | c.5303C>T p.T1768I | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); catalogued as COSV100615382; called by muse, mutect2, varscan2
- SALL3 | c.2674G>A p.G892S | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV101609973; called by muse, mutect2
- SCGB1D2 | c.118C>T p.P40S | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.85); PolyPhen benign (0.437); catalogued as COSV99793552; called by muse, mutect2, varscan2
- SEMA3F | c.1745+1G>C p.X582_splice | Splice Site (SNP) | VAF 31/82 reads (38%) | catalogued as COSV99137314; called by muse, mutect2, varscan2
- SERPINI1 | c.1221C>G p.F407L | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.087); catalogued as COSV55508226, COSV99854969; called by muse, mutect2, varscan2
- SIM2 | c.392C>A p.S131Y | Missense Mutation (SNP) | VAF 78/274 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.261); catalogued as COSV99293108; called by muse, mutect2, varscan2
- SLC14A2 | c.2392A>G p.T798A | Missense Mutation (SNP) | VAF 52/160 reads (33%) | SIFT tolerated (0.98); PolyPhen benign (0.055); catalogued as rs745701732, COSV99675333; called by muse, mutect2, varscan2
- SLC24A3 | c.1292A>G p.D431G | Missense Mutation (SNP) | VAF 16/201 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV100040598; called by muse, mutect2
- SLC2A7 | c.950C>T p.A317V | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.209); catalogued as COSV101280769; called by muse, mutect2, varscan2
- SLC4A7 | c.1739+2T>C p.X580_splice | Splice Site (SNP) | VAF 22/51 reads (43%) | catalogued as COSV99839550; called by muse, varscan2
- SLC5A7 | c.803C>T p.T268I | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0.296); catalogued as COSV99886539; called by muse, mutect2, varscan2
- SLCO6A1 | c.1382C>A p.T461K | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV101134218; called by muse, mutect2, varscan2
- SMTNL1 | c.886C>A p.R296S (on ENST00000399154; = p.R333S on NM_001105565.2) | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as COSV101216311; called by muse, mutect2, varscan2
- SORL1 | c.6571G>A p.D2191N | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as rs1023106909, COSV99492502, COSV99493449; called by muse, mutect2, varscan2
- SPEF2 | c.4096C>T p.R1366* | Nonsense Mutation (SNP) | VAF 5/36 reads (14%) | catalogued as rs772743570, COSV57429067; called by muse, mutect2, varscan2
- SPG7 | c.1279A>T p.N427Y (on ENST00000268704; = p.N434Y on NM_003119.4) | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99244810; called by muse, mutect2, varscan2
- SQLE | c.1234A>G p.M412V | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.014); catalogued as COSV99772263; called by muse, mutect2, varscan2
- STIL | c.358G>T p.G120W | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99680814; called by muse, mutect2, varscan2
- STX3 | c.157G>T p.V53L | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.894); catalogued as COSV55695561; called by muse, mutect2, varscan2
- SUPT20H | c.89C>G p.S30* | Nonsense Mutation (SNP) | VAF 8/27 reads (30%) | catalogued as COSV100634633; called by muse, mutect2, varscan2
- TACC2 | c.6460C>T p.Q2154* (on ENST00000334433; = p.Q232* on NM_006997.4) | Nonsense Mutation (SNP) | VAF 84/306 reads (27%) | catalogued as COSV99586923; called by muse, mutect2, varscan2
- TP53 | c.357del p.K120Sfs*3 | Frame Shift Del (DEL) | VAF 32/107 reads (30%) | catalogued as COSV52702653, COSV52827728; called by mutect2, pindel, varscan2
- TP53INP1 | c.696G>T p.Q232H | Missense Mutation (SNP) | VAF 61/167 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as COSV100711042; called by muse, mutect2, varscan2
- TRDN | c.180G>A p.W60* | Nonsense Mutation (SNP) | VAF 34/130 reads (26%) | catalogued as COSV100521546; called by muse, varscan2
- TSSK3 | c.511G>A p.G171S | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748163709, COSV100344601; called by muse, mutect2, varscan2
- TTN | c.77339C>T p.S25780L (on ENST00000591111; = p.S18356L on NM_003319.4) | Missense Mutation (SNP) | VAF 28/63 reads (44%) | PolyPhen benign (0.121); catalogued as COSV100605004; called by muse, mutect2, varscan2
- TTN | c.27596del p.R9199Lfs*8 (on ENST00000591111; = p.R8272Lfs*8 on NM_133378.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 17/51 reads (33%) | catalogued as COSV60173821; called by mutect2, pindel*, varscan2
- UBA3 | c.1271G>T p.R424L | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV100734664, COSV62741518; called by muse, mutect2, varscan2
- UNC79 | c.2175A>T p.R725S (on ENST00000393151 / NM_001346218.2; = p.R548S on NM_020818.5) | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.423); catalogued as COSV99827096; called by muse, mutect2, varscan2
- USP25 | c.223C>G p.P75A | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.057); catalogued as COSV99583546; called by muse, mutect2, varscan2
- USP30 | c.133C>G p.L45V | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.056); catalogued as rs1196668772, COSV104379675, COSV57451140, COSV99980316; called by muse, mutect2, varscan2
- WDR3 | c.1732G>A p.V578I | Missense Mutation (SNP) | VAF 53/159 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0.057); catalogued as rs760784329, COSV100308694; called by muse, mutect2, varscan2
- WDR90 | c.2350C>T p.R784* | Nonsense Mutation (SNP) | VAF 10/23 reads (43%) | catalogued as rs751329037, COSV99553122; called by muse, varscan2
- WWC2 | c.2360A>G p.D787G | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.468); catalogued as COSV100968259; called by muse, mutect2, varscan2
- ZEB1 | c.2818G>C p.A940P | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV100314108, COSV58055722; called by muse, mutect2, varscan2
- ZFP30 | c.1070A>G p.K357R | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.622); catalogued as COSV100665856; called by muse, mutect2, varscan2
- ZFPM2 | c.3314C>A p.A1105E | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.023); catalogued as COSV101023149; called by muse, mutect2, varscan2
- ZNF274 | c.1397T>C p.V466A (on ENST00000610905; = p.V361A on NM_016324.3) | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as COSV100464956; called by muse, mutect2, varscan2
- ZNF417 | c.1184T>G p.L395R | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100364177; called by muse, mutect2
- ZNF485 | c.323G>A p.R108Q | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs774582254, COSV62425407; called by muse, mutect2, varscan2
- ZNF518B | c.1045G>C p.D349H | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100456644, COSV58723820; called by muse, mutect2, varscan2
- ZNF699 | c.812A>G p.K271R | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100426915; called by muse, mutect2, varscan2
- ZNRF4 | c.699C>A p.H233Q | Missense Mutation (SNP) | VAF 47/191 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as rs200409035, COSV99706458; called by muse, mutect2, varscan2
- ZRANB1 | c.931G>A p.V311I | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as COSV100669116; called by muse, mutect2, varscan2
- ESCO1 | c.1030dup p.T344Nfs*4 | Frame Shift Ins (INS) | VAF 12/51 reads (24%) | called by mutect2, pindel, varscan2
- MTMR12 | c.1116dup p.A373Sfs*99 | Frame Shift Ins (INS) | VAF 8/26 reads (31%) | called by mutect2, pindel, varscan2
- OR6M1 | c.712dup p.C238Lfs*31 | Frame Shift Ins (INS) | VAF 10/58 reads (17%) | called by mutect2, pindel, varscan2
- OTOGL | c.2110del p.H704Tfs*126 (on ENST00000547103; = p.H695Tfs*126 on NM_173591.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 29/176 reads (16%) | called by mutect2, pindel, varscan2
- PCDHB16 | c.1567G>T p.A523S | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- PDCD6 | c.490_493del p.I164Sfs*33 | Frame Shift Del (DEL) | VAF 39/132 reads (30%) | called by mutect2, pindel, varscan2
- PTPRZ1 | c.6296dup p.L2100Pfs*15 | Frame Shift Ins (INS) | VAF 39/153 reads (25%) | called by mutect2, pindel, varscan2
- TAF5 | c.1694_1695del p.G565Dfs*3 | Frame Shift Del (DEL) | VAF 11/48 reads (23%) | called by mutect2, pindel, varscan2
- TPRA1 | c.569del p.G190Afs*27 | Frame Shift Del (DEL) | VAF 16/101 reads (16%) | called by mutect2, pindel, varscan2
- ZNF823 | c.320del p.V107Afs*130 (on ENST00000341191 / NM_001297610.2; = p.V63Afs*130 on NM_017507.2) | Frame Shift Del (DEL) | VAF 16/69 reads (23%) | called by mutect2, pindel, varscan2
- ADAM11 | c.1572G>T p.P524= | Silent (SNP) | VAF 31/104 reads (30%) | catalogued as COSV52348509, COSV99567315; called by muse, mutect2, varscan2
- ADAMTS10 | c.2091G>T p.V697= | Silent (SNP) | VAF 37/161 reads (23%) | catalogued as COSV99546747; called by muse, mutect2, varscan2
- ADGRB2 | c.1347G>A p.A449= | Silent (SNP) | VAF 24/80 reads (30%) | catalogued as rs754427588, COSV99926014; called by muse, mutect2, varscan2
- ADGRL2 | c.2100C>T p.S700= (on ENST00000370717 / NM_001366005.1; = p.S687= on NM_012302.4) | Silent (SNP) | VAF 19/82 reads (23%) | catalogued as rs139486341, COSV54663040; called by muse, mutect2, varscan2
- AFTPH | c.969T>C p.D323= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as COSV99480505; called by muse, mutect2, varscan2
- AOX1 | c.1077C>T p.I359= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as COSV101021878; called by muse, mutect2
- ARSL | c.207T>G p.L69= | Silent (SNP) | VAF 16/31 reads (52%) | catalogued as COSV101140475; called by muse, mutect2, varscan2
- BCL6 | c.171C>T p.F57= | Silent (SNP) | VAF 26/56 reads (46%) | catalogued as COSV99215553; called by muse, mutect2, varscan2
- CAP1 | c.873T>C p.G291= | Silent (SNP) | VAF 29/280 reads (10%) | catalogued as rs373976739; called by muse, mutect2, varscan2
- CC2D2B | c.447T>C p.H149= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as rs751118258, COSV100729359; called by muse, mutect2, varscan2
- CEP170 | c.1776C>G p.A592= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV100316832; called by muse, mutect2, varscan2
- CEP83 | c.1221T>C p.D407= | Silent (SNP) | VAF 9/69 reads (13%) | catalogued as COSV100352786; called by muse, mutect2
- CHMP1B | c.423G>T p.T141= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as COSV99303327; called by muse, mutect2, varscan2
- CLRN3 | c.453G>C p.T151= | Silent (SNP) | VAF 28/103 reads (27%) | catalogued as COSV100899753; called by muse, mutect2, varscan2
- CTNNA1 | c.900C>T p.R300= | Silent (SNP) | VAF 9/68 reads (13%) | catalogued as COSV100242510; called by muse, mutect2, varscan2
- CUX1 | c.99G>A p.R33= (on ENST00000292535 / NM_181552.4; = p.R44= on NM_001913.5) | Silent (SNP) | VAF 86/304 reads (28%) | catalogued as rs1563004831, COSV99471121; called by muse, mutect2, varscan2
- DNMT3B | c.468G>T p.T156= | Silent (SNP) | VAF 113/372 reads (30%) | catalogued as COSV99140928; called by muse, mutect2, varscan2
- DTX2 | c.1710G>A p.T570= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as rs765433775, COSV100184526; called by muse, mutect2, varscan2
- FAM47C | c.1560C>G p.S520= | Silent (SNP) | VAF 80/127 reads (63%) | catalogued as COSV100792440; called by muse, mutect2, varscan2
- FAM71C | c.210A>T p.T70= | Silent (SNP) | VAF 18/191 reads (9%) | catalogued as COSV100175719; called by muse, mutect2
- FASTK | c.1170C>T p.L390= | Silent (SNP) | VAF 19/62 reads (31%) | catalogued as rs769664047, COSV99879677; called by muse, mutect2, varscan2
- FBXL4 | c.1446G>T p.R482= | Silent (SNP) | VAF 22/85 reads (26%) | catalogued as COSV100014018; called by muse, mutect2, varscan2
- FH | c.867T>C p.F289= | Silent (SNP) | VAF 29/110 reads (26%) | catalogued as COSV100845006; called by muse, mutect2, varscan2
- GATAD2B | c.303T>C p.N101= | Silent (SNP) | VAF 33/162 reads (20%) | catalogued as COSV100897845; called by muse, mutect2, varscan2
- GIMAP5 | c.348G>A p.L116= | Silent (SNP) | VAF 56/183 reads (31%) | catalogued as COSV100500226; called by muse, mutect2, varscan2
- GNE | c.159T>C p.Y53= (on ENST00000396594 / NM_001128227.3; = p.Y22= on NM_005476.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 22/76 reads (29%) | catalogued as COSV100929933; called by muse, mutect2, varscan2
- HGFAC | c.984C>T p.A328= | Silent (SNP) | VAF 14/26 reads (54%) | catalogued as rs573243423, COSV101237741; called by muse, varscan2
- HMCN1 | c.10701G>A p.R3567= | Silent (SNP) | VAF 20/71 reads (28%) | catalogued as COSV99627420; called by muse, mutect2, varscan2
- IGF2BP1 | c.1428G>A p.E476= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as COSV51731784; called by muse, mutect2, varscan2
- IGFBP5 | c.646C>T p.L216= | Silent (SNP) | VAF 4/95 reads (4%) | catalogued as rs1206663692, COSV99288887; called by muse, mutect2
- KHDRBS1 | c.858G>T p.V286= | Silent (SNP) | VAF 45/140 reads (32%) | catalogued as COSV56982083; called by muse, mutect2, varscan2
- KIFAP3 | c.1050G>T p.V350= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as rs763820904, COSV100810951; called by muse, mutect2, varscan2
- KRT71 | c.1296T>C p.Y432= | Silent (SNP) | VAF 30/160 reads (19%) | catalogued as rs753124470, COSV99922092; called by muse, mutect2, varscan2
- LILRA5 | c.438C>A p.A146= | Silent (SNP) | VAF 49/184 reads (27%) | catalogued as COSV100006872; called by muse, mutect2, varscan2
- LRIT1 | c.1752G>A p.L584= | Silent (SNP) | VAF 22/64 reads (34%) | catalogued as COSV100928061; called by muse, mutect2, varscan2
- LRRC15 | c.333C>T p.N111= | Silent (SNP) | VAF 37/129 reads (29%) | catalogued as COSV100752648; called by muse, mutect2, varscan2
- LRRC8C | c.2307T>A p.P769= | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as COSV100968192; called by muse, mutect2, varscan2
- LRRK1 | c.4569G>A p.P1523= | Silent (SNP) | VAF 45/147 reads (31%) | catalogued as rs201190527, COSV99439037, COSV99440357; called by muse, mutect2, varscan2
- LY6E | c.132G>A p.Q44= | Silent (SNP) | VAF 34/161 reads (21%) | catalogued as COSV99465030; called by muse, mutect2, varscan2
- MARS2 | c.711A>C p.P237= | Silent (SNP) | VAF 28/69 reads (41%) | catalogued as COSV99986554; called by muse, mutect2, varscan2
- ME1 | c.1659A>T p.L553= | Silent (SNP) | VAF 5/72 reads (7%) | catalogued as COSV100866442; called by muse, mutect2
- MYH9 | c.3003A>T p.I1001= | Silent (SNP) | VAF 52/178 reads (29%) | catalogued as COSV99338493; called by muse, mutect2, varscan2
- NBPF10 | c.1212G>A p.P404= | Silent (SNP) | VAF 75/267 reads (28%) | catalogued as rs782499029, COSV61659389; called by muse, mutect2, varscan2
- NEUROD6 | c.549C>A p.L183= | Silent (SNP) | VAF 28/93 reads (30%) | catalogued as COSV99773981; called by muse, mutect2, varscan2
- NLK | c.387G>T p.S129= | Silent (SNP) | VAF 44/179 reads (25%) | catalogued as rs1385812212, COSV101311030, COSV69410295; called by muse, mutect2, varscan2
- NLRP1 | c.2814C>T p.G938= | Silent (SNP) | VAF 28/59 reads (47%) | catalogued as rs772089891, COSV52559344; called by muse, mutect2, varscan2
- NTRK1 | c.1716C>T p.I572= | Silent (SNP) | VAF 37/87 reads (43%) | catalogued as rs759767777, COSV62328128; called by muse, mutect2, varscan2
- OAS3 | c.990G>T p.L330= | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as COSV99966212; called by muse, mutect2, varscan2
- OR2A4 | c.126G>A p.G42= | Silent (SNP) | VAF 22/170 reads (13%) | catalogued as COSV100199654; called by muse, varscan2
- OR56A4 | c.981C>A p.V327= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as rs749020429, COSV100417532, COSV58109326; called by muse, mutect2, varscan2
- OR5M11 | c.18C>T p.G6= | Silent (SNP) | VAF 19/89 reads (21%) | catalogued as COSV101602030; called by muse, mutect2, varscan2
- P2RX4 | c.102C>A p.A34= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as rs368099159, COSV100078707; called by muse, varscan2
- PCBP1 | c.501G>T p.L167= | Silent (SNP) | VAF 30/99 reads (30%) | catalogued as COSV100340119; called by muse, mutect2, varscan2
- PCDHB9 | c.387C>T p.H129= | Silent (SNP) | VAF 32/51 reads (63%) | called by muse, mutect2, varscan2
- PHKA1 | c.2091C>T p.C697= | Silent (SNP) | VAF 29/48 reads (60%) | catalogued as rs782416080, COSV100262871; called by muse, mutect2, varscan2
- PIK3C2B | c.2142C>T p.I714= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as rs893981470, COSV100915979, COSV100916055, COSV65811405; called by muse, mutect2, varscan2
- PIWIL1 | c.1878G>T p.V626= | Silent (SNP) | VAF 43/138 reads (31%) | catalogued as COSV99806244; called by muse, mutect2, varscan2
- PRUNE2 | c.8073C>T p.A2691= | Silent (SNP) | VAF 33/63 reads (52%) | catalogued as COSV100944430; called by muse, mutect2, varscan2
- SALL1 | c.2037C>A p.L679= | Silent (SNP) | VAF 33/117 reads (28%) | catalogued as COSV99173156; called by muse, mutect2, varscan2
- SELENBP1 | c.318G>T p.V106= | Silent (SNP) | VAF 44/157 reads (28%) | catalogued as COSV100923628; called by muse, mutect2, varscan2
- SIDT2 | c.1575C>A p.I525= | Silent (SNP) | VAF 10/246 reads (4%) | catalogued as COSV99637508; called by muse, mutect2
- SIPA1L3 | c.4830C>T p.P1610= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs753354592, COSV99728218; called by muse, varscan2
- SKIL | c.405C>G p.L135= | Silent (SNP) | VAF 63/321 reads (20%) | catalogued as COSV99378187, COSV99378523; called by muse, mutect2, varscan2
- SORCS1 | c.1104A>T p.P368= | Silent (SNP) | VAF 25/75 reads (33%) | catalogued as COSV99545200; called by muse, mutect2, varscan2
- STK16 | c.393G>A p.G131= | Silent (SNP) | VAF 21/41 reads (51%) | catalogued as COSV99850445; called by muse, mutect2, varscan2
- TBX22 | c.378G>A p.R126= | Silent (SNP) | VAF 38/66 reads (58%) | catalogued as COSV100960724; called by muse, mutect2, varscan2
- TRIO | c.2979G>A p.A993= | Silent (SNP) | VAF 50/198 reads (25%) | catalogued as rs570447608, COSV100710201; called by muse, mutect2, varscan2
- ZNF100 | c.1410A>G p.S470= | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as COSV99973913; called by muse, mutect2, varscan2
- ZNF417 | c.1185C>G p.L395= | Silent (SNP) | VAF 9/151 reads (6%) | catalogued as COSV100364048, COSV100364174; called by muse, mutect2
- ZNF516 | c.2760G>A p.P920= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as rs371471184; called by muse, mutect2, varscan2
- ZNF804B | c.399A>C p.P133= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV100303015; called by muse, mutect2, varscan2
- DAZAP1 | c.1049-998G>T | Intron (SNP) | VAF 52/154 reads (34%) | catalogued as COSV99245136; called by muse, mutect2, varscan2
- MAP4 | c.1999+5095G>T | Intron (SNP) | VAF 18/44 reads (41%) | catalogued as COSV99275050; called by muse, mutect2, varscan2
- MIR129-2 | n.20T>A | RNA (SNP) | VAF 16/26 reads (62%) | called by muse, mutect2, varscan2
- RUSC1 | c.-87+279C>G | Intron (SNP) | VAF 7/37 reads (19%) | catalogued as COSV99429670; called by muse, mutect2, varscan2
- TEX2 | chr17:64146428 G>T | 3'Flank (SNP) | VAF 50/191 reads (26%) | catalogued as rs754667246; called by muse, mutect2, varscan2
